Somatic mutation profile of tumor specimen TARGET-10-PASPPN-09A (aliquot TARGET-10-PASPPN-09A-01D) from TARGET case TARGET-10-PASPPN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.6 years (4,593 days).
Specimen TARGET-10-PASPPN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e43da61-c023-4e37-8af6-27f7282238c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASPPN-10A (Blood Derived Normal), aliquot TARGET-10-PASPPN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2ae39a0-5b6d-43f8-bcd0-f9e70dfc151c

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Intron 3, RNA 2, Frame Shift Ins 2, 3'UTR 1, 5'Flank 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 12/12 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 55/132 reads (42%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 19/31 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 60/136 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACOT11 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776181783, COSV56363572; called by muse, mutect2, varscan2
- ANKRD1 | c.831T>A p.D277E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs1376171458; called by muse, mutect2, varscan2
- BSN | c.9338G>A p.R3113H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs140240631; called by muse, mutect2, varscan2
- CHSY3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs151036314; called by muse, mutect2, varscan2
- DNM2 | c.1603A>G p.K535E (on ENST00000355667 / NM_001005360.3; = p.K531E on NM_004945.3) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV58970956; called by muse, mutect2, varscan2
- FAM83A | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52683768, COSV52685899; called by muse, mutect2, varscan2
- GLI3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750890677, COSV67889940; called by muse, mutect2, varscan2
- HS2ST1 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV59357065; called by muse, mutect2, varscan2
- KCNJ1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs779864905, CD075449, COSV60662725; called by muse, mutect2, varscan2
- LDHC | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs201168555, COSV55004333; called by muse, mutect2, varscan2
- LRATD1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54474106; called by muse, mutect2, varscan2
- NOTCH1 | c.7210C>T p.Q2404* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs1554826400, COSV53029648, COSV99493174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.5161G>A p.V1721M | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039416; called by muse, mutect2, varscan2
- NRXN3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs368733653; called by muse, mutect2, varscan2
- PCDHGA11 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); catalogued as COSV53914568; called by muse, mutect2, varscan2
- PCIF1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as rs1370088899, COSV59818769; called by muse, mutect2, varscan2
- PDE8A | c.2186A>G p.N729S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749820671, COSV59640159; called by muse, mutect2, varscan2
- PPM1F | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs774522572, COSV54286470; called by muse, mutect2, varscan2
- RALGAPA1 | c.4798C>T p.R1600C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490577779; called by muse, mutect2, varscan2
- SLC5A8 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs750721928, COSV73311155; called by muse, mutect2, varscan2
- SUZ12 | c.1801_1802insGG p.E601Gfs*14 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as COSV59503076; called by mutect2, pindel*, varscan2*
- ALDH18A1 | c.1210C>T p.L404= | Silent (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- CCDC85A | c.837G>A p.P279= | Silent (SNP) | VAF 90/174 reads (52%) | catalogued as rs755921410, COSV101339474, COSV101339518; called by muse, mutect2, varscan2
- HLX | c.912G>A p.P304= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs776103225, COSV100854446; called by muse, varscan2
- LGALS8 | c.126C>T p.D42= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as rs767712880; called by muse, mutect2, varscan2
- AC027612.1 | n.699C>T | RNA (SNP) | VAF 10/31 reads (32%) | catalogued as rs1406660019; called by muse, mutect2, varscan2
- GANAB | c.561-91_561-90insGGGTGGGG | Intron (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- GLRX5 | c.296-134A>G | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- GPER1 | c.*410G>A | 3'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- KIF25 | c.317+1601G>A | Intron (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- OR5P1P | n.635G>T | RNA (SNP) | VAF 70/127 reads (55%) | called by muse, mutect2, varscan2
- POLR3D | chr8:22245016 G>C | 5'Flank (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- TUBGCP4 | chr15:43407646 T>C | 3'Flank (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
